Somatic mutation profile of tumor specimen TARGET-40-NAAWGR-01A (aliquot TARGET-40-NAAWGR-01A-01D) from TARGET case TARGET-40-NAAWGR, project TARGET-OS (Osteosarcoma). Sex at birth: female; Primary diagnosis: Osteosarcoma, NOS; Age at diagnosis: 14.0 years (5,110 days).
Specimen TARGET-40-NAAWGR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5486e2e3-05bd-4aaa-8b88-7677773057d0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAWGR-10A (Blood Derived Normal), aliquot TARGET-40-NAAWGR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/258d396b-f20f-4e9b-a494-048fc3acec1d

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.559+2_559+7delinsG p.X187_splice | Splice Site (DEL) | VAF 8/36 reads (22%) | hotspot (GDC flag); called by pindel, varscan2*
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 29/46 reads (63%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- CSTF3 | c.1795del p.P599Lfs*21 | Frame Shift Del (DEL) | VAF 20/204 reads (10%) | catalogued as COSV100124445; called by mutect2, pindel, varscan2
- DHX36 | c.2452G>C p.D818H | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as COSV100273382; called by muse, mutect2
- EGFR | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV51788192, COSV51837721; called by muse, varscan2
- GRM5 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59629094; called by muse, mutect2, varscan2
- MUC16 | c.42469C>A p.L14157M | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as rs775099973, COSV66696432; called by muse, mutect2
- SYNE1 | c.10229C>A p.A3410D (on ENST00000367255 / NM_182961.4; = p.A3417D on NM_033071.3) | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99580017; called by muse, mutect2
- ADGRG2 | c.600T>G p.C200W (on ENST00000379869 / NM_001079858.3; = p.C197W on NM_005756.4) | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ATRX | c.706del p.H236Ifs*21 | Frame Shift Del (DEL) | VAF 91/171 reads (53%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.4659G>T p.Q1553H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAPPC9 | c.1726A>G p.I576V | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- GJA5 | c.678C>A p.L226= | Silent (SNP) | VAF 32/136 reads (24%) | called by muse, mutect2, varscan2
- RYR2 | c.13548C>A p.I4516= | Silent (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- ZNF649 | c.156C>A p.G52= | Silent (SNP) | VAF 7/151 reads (5%) | catalogued as COSV61617208; called by muse, mutect2
